Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NE, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NE-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

A -year-old male with distal esophageal adenocarcinoma, likely arising in Barrett's mucosa associated with longstanding GE reflux.

PROCEDURE:

VERIFIED BY:

1. "Thoracic esophagus" A 9 cm distal esophagus with attached 5 cm proximal stomach contains a well-circumscribed 5.7 x 4.5 cm polypoid tan-brown tumor occupying 80% of the circumference, and is 1.1 cm from the distal gastric margin and 7.2 cm from the proximal esophageal margin. The tumor is 2/3 within the esophageal space and 1/3 in the gastric space. Adjacent to the tumor and contiguous with it is a 1.8 x 1.2 cm area of ulceration at the GE junction. The remainder of the esophageal and gastric mucosae appear unremarkable. Deep margin inked black, distal margin inked blue. The tumor is 1.8 cm thick and penetrates into the surrounding adipose. There are several lymph nodes up to 1 cm in the adipose.

1A.-D. Tumor at its greatest extent.

1E. Tumor in relation to esophagus.

1F. Tumor in relation to stomach and distal margin.

1G. Ulcer adjacent to tumor.

1H. Lymph nodes.

1I. Lymph nodes.

2. "Cervical esophageal margin" A 1 cm length of esophagus is received with a stapled end and an opened end. Opened end inked blue.

100-0-3
Adenocarcinoma NOS 8140/3
Site Esophagus, distal third
0155
JW 1/17/14

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma.

If adenocarcinoma, is it arising in: G-E junction.

Depth of invasion: Muscularis propria.

Number of positive lymph nodes, the total number sampled is irrelevant: 1

Extranodal metastasis: Unknown.

Pattern of invasion: Infiltrative.

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Esophageal and gastric resection margins involved: No.

Deep resection margin involved: No.

TNM classification: T2 N1 Mx

PROCEDURE:

VERIFIED BY:

1. Thoracic esophagus and stomach, partial resection: Invasive adenocarcinoma arising at esophago-gastric junction extending into muscularis propria. Margins free. One of twelve lymph nodes positive for metastatic carcinoma. See template.

2. Esophagus, cervical margin, resection: Esophagus. Negative for neoplasm.

I, . M.D., the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

hTAA Discrepancy		/
Minor Malignancy History		/
Dual/Multifocal Primary Noted		/

Source: NCI Genomic Data Commons file d5660fd4-1e63-42df-b8bf-dc5ed107c4d2 (TCGA-L5-A8NE.7D02A80A-4842-4A59-87A2-257D275C875C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).